Gene-level copy-number profile of tumor specimen TCGA-BA-5555-01A from TCGA case TCGA-BA-5555, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 54.6 years (19,956 days).
Specimen TCGA-BA-5555-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.1e837b07-abff-4986-9ef7-d8a40312e103.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BA-5555-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/06c2f06d-4803-4a2d-944a-99bffed1a968

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 49; copy number 2: 20,409; copy number 3: 17,397; copy number 4: 14,512; copy number 5: 4,139; copy number 6: 1,337; copy number 7: 1,753; copy number 8: 16; copy number 9: 54; copy number 10: 144.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BA-5555-01A-01D-1510-01): tumor purity 0.46, ploidy 3.18, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:178,493,327–178,493,810, 1 gene: PPIAP75.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7,443 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–210,267,241, 1,761 genes, copy number 5 (broad region; genes not listed).
- chr2:174,487,380–176,339,077, 46 genes, copy number 5: AC010894.1, RPA3P1, AC010894.4, AC010894.2, RNU6-5P, WIPF1, AC010894.3, H3P6, CHRNA1, CHN1, RNU6-763P, RNU6-1290P, RPL21P31, ATF2, AC007435.1, MIR933, AC096649.1, ATP5MC3, Y_RNA, RPS15AP14, AC093459.1, EXTL2P1, AC016751.2, AC016751.1, LNPK, EVX2, HOXD13, HOXD12, HOXD11, HOXD10, HOXD-AS2, HOXD9, HOXD8, HOXD3, MIR10B, HOXD4, HAGLR, AC009336.1, HAGLROS, HOXD1, MIR7704, AC009336.2, AC016739.1, RPSAP25, MTX2, PPIAP67.
- chr2:176,506,245–176,637,931, 5 genes, copy number 5: AC017048.1, AC017048.2, MIR1246, AC017048.3, LINC01116.
- chr3:130,850,595–131,016,712, 1 gene, copy number 7 (within-gene range 2–7): ATP2C1.
- chr3:130,899,414–178,844,429, 709 genes, copy number 7 (within-gene range 0–7) (broad region; genes not listed).
- chr3:178,526,505–190,145,107, 245 genes, copy number 7–10 (within-gene range 0–10) (broad region; genes not listed).
- chr4:183,444,635–183,517,527, 5 genes, copy number 5: CDKN2AIP, VTI1BP2, AC107214.1, ING2, AC107214.2.
- chr5:58,198–45,895,970, 710 genes, copy number 7 (broad region; genes not listed).
- chr5:50,858,760–52,080,987, 20 genes, copy number 7: AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P, AC026798.1, AC010478.1, ISL1, HMGB1P47, AC091860.1, AC022433.1, AC091860.2, RNA5SP182, KATNBL1P4, AC091903.1, LINC02118.
- chr6:167,607–58,438,364, 1,527 genes, copy number 6–7 (broad region; genes not listed).
- chr7:51,716,657–62,275,678, 179 genes, copy number 5 (broad region; genes not listed).
- chr8:46,028,804–51,015,165, 77 genes, copy number 7–9 (broad region; genes not listed).
- chr8:127,253,213–127,742,951, 9 genes, copy number 6: AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC.
- chr8:127,795,962–127,890,720, 2 genes, copy number 6: MIR1204, AC084123.1.
- chr10:36,089,086–38,378,505, 45 genes, copy number 5: AL355300.1, MTND5P17, MTND4P18, AL590730.1, AL590730.2, NAMPTP1, Y_RNA, AL390061.1, MKNK2P1, ARL6IP1P2, ANKRD30A, RNU6-811P, AL157387.1, LINC00993, RN7SL314P, Y_RNA, TMEM161BP1, VN1R53P, TACC1P1, MTND1P18, MTRNR2L7, AL132657.1, ZNF248, AL132657.2, ZNF33BP1, TLK2P2, AL135791.1, ZNF37CP, ZNF33CP, ZNF25, ZNF25-DT, Y_RNA, ZNF33A, RNU6-795P, AL161931.1, EIF3LP3, FXYD6P2, ZNF37A, AL117339.4, AL117339.3, AL117339.1, CCNYL4, AL133217.1, AL117339.2, HSD17B7P2.
- chr11:66,744,451–95,234,391, 722 genes, copy number 5 (broad region; genes not listed).
- chr12:90,576,402–90,889,917, 4 genes, copy number 6: LINC02822, AC084365.1, AC112481.2, AC112481.1.
- chr22:15,290,718–50,801,309, 1,376 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 41. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
